Somatic mutation profile of tumor specimen TCGA-BR-8677-01A (aliquot TCGA-BR-8677-01A-11D-2394-08) from TCGA case TCGA-BR-8677, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 74.5 years (27,223 days).
Specimen TCGA-BR-8677-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 585c8bb7-9910-4f62-a85d-15c64791bd6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8677-10A (Blood Derived Normal), aliquot TCGA-BR-8677-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a05e1c3-67c5-454a-8297-9a83c11015cf

The open-access MAF lists 73 somatic variants for this specimen: 52 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 19, Nonsense Mutation 4, 3'UTR 1, In Frame Del 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTRT1 | c.1125C>A p.C375* | Nonsense Mutation (SNP) | VAF 6/126 reads (5%) | catalogued as COSV64419094; called by muse, mutect2
- ADAMTS19 | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.925); catalogued as COSV50737531, COSV50769344; called by muse, mutect2, varscan2
- AGMO | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.085); catalogued as COSV61108817; called by muse, mutect2, varscan2
- CDH8 | c.2094G>T p.K698N | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV54856898; called by muse, mutect2
- CRISPLD1 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.251); catalogued as COSV51545888; called by muse, mutect2
- CSMD3 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52090752, COSV52136577, COSV52142448; called by muse, mutect2, varscan2
- CXorf21 | c.276T>G p.F92L | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as COSV100973286; called by muse, mutect2
- D2HGDH | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58319776; called by muse, mutect2, varscan2
- ENPP3 | c.1308C>G p.F436L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as COSV62956018; called by muse, mutect2
- GLP2R | c.1456G>A p.G486S | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52323268; called by muse, mutect2
- GRM5 | c.804G>T p.L268F | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV59597519; called by muse, mutect2, varscan2
- H2AC11 | c.223A>T p.K75* | Nonsense Mutation (SNP) | VAF 18/170 reads (11%) | catalogued as COSV100345805, COSV60361870; called by muse, mutect2, varscan2
- HIRA | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99600398; called by muse, mutect2
- KCND2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.909); catalogued as COSV58579127; called by muse, mutect2
- LNX2 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as rs1451648056, COSV100310721; called by muse, mutect2, varscan2
- LRRN2 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762590445, COSV65783436; called by muse, mutect2
- MAB21L1 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100080093; called by muse, mutect2
- MINK1 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.885); catalogued as rs1166428542, COSV61789366; called by muse, mutect2, varscan2
- NBEAL2 | c.4220C>A p.S1407Y | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52755802; called by mutect2, varscan2
- NTSR1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1490709349; called by muse, mutect2
- OR2W1 | c.89T>G p.V30G | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV65851478; called by muse, mutect2
- PCDHGA2 | c.30C>A p.C10* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as rs1488637412, COSV101120197; called by muse, mutect2, varscan2
- PHIP | c.1495G>A p.G499R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99244181; called by muse, mutect2, varscan2
- PLXND1 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1214289026, COSV60710916; called by muse, mutect2
- PRMT9 | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV59359154; called by muse, mutect2, varscan2
- PROS1 | c.873G>C p.L291F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.844); catalogued as COSV67774794; called by muse, mutect2, varscan2
- PSG7 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV68444682; called by muse, mutect2
- RAB39B | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV65624487; called by muse, mutect2
- RBM3 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1431772705, COSV63202405, COSV63202567; called by muse, mutect2, varscan2
- RHBDF1 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs368764349, COSV51954278; called by muse, mutect2, varscan2
- SALL1 | c.1933C>G p.P645A | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV51755268, COSV51757236; called by muse, mutect2, varscan2
- SCUBE2 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs376851791; called by muse, mutect2, varscan2
- SERPING1 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.191); catalogued as COSV53541937; called by muse, mutect2, varscan2
- SKAP1 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.111); catalogued as COSV61145385; called by muse, mutect2, varscan2
- SLC44A4 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs774489026, COSV57666541; called by muse, mutect2, varscan2
- SLC6A13 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201579126; called by muse, mutect2, varscan2
- SLK | c.2942A>C p.Q981P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59824523; called by muse, mutect2, varscan2
- SPA17 | c.215A>G p.H72R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.357); catalogued as COSV57032097; called by muse, mutect2, varscan2
- SPAG1 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99308998; called by muse, mutect2
- TG | c.2404C>A p.L802M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV55070393; called by muse, mutect2, varscan2
- TGFBR1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223832, COSV66625229, COSV66627552; ClinVar: uncertain significance; called by muse, varscan2
- TRAK1 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as COSV59640698; called by muse, mutect2
- TREML2 | c.887G>T p.S296I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV72439068; called by muse, mutect2
- TUBGCP6 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs756253050, COSV50539489; called by muse, mutect2, varscan2
- UBQLN3 | c.667T>C p.F223L | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV61163658; called by muse, mutect2
- UNC5A | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188651353, COSV56166471; called by muse, mutect2
- ZNF273 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1195928904, COSV60398068; called by muse, mutect2, varscan2
- ZNF468 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs939838900, COSV54693854; called by muse, mutect2
- ZNF480 | c.135C>G p.D45E | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV57995265; called by muse, mutect2
- ZSCAN10 | c.938G>A p.R313H (on ENST00000252463; = p.R368H on NM_032805.3) | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs753924880, COSV52967337, COSV52968391; called by muse, mutect2, varscan2
- CDH1 | c.948_950del p.M316_F317delinsI | In Frame Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- SLITRK2 | c.2382_2385del p.N794Kfs*92 | Frame Shift Del (DEL) | VAF 24/138 reads (17%) | called by mutect2, pindel, varscan2
- AGR2 | c.87C>T p.A29= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV68596323; called by muse, mutect2
- C5orf38 | c.282C>T p.V94= | Silent (SNP) | VAF 8/129 reads (6%) | catalogued as COSV57410448, COSV57411008; called by muse, mutect2
- CAVIN1 | c.1041C>T p.D347= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV63811579; called by muse, mutect2, varscan2
- GABBR2 | c.1545G>A p.S515= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs374493679, COSV52298550; called by muse, mutect2, varscan2
- GTSE1 | c.2010C>T p.I670= | Silent (SNP) | VAF 33/192 reads (17%) | catalogued as COSV71888984; called by muse, mutect2, varscan2
- HIVEP3 | c.3294C>T p.P1098= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as rs537713789, COSV56012457; called by muse, mutect2, varscan2
- HSPB3 | c.228C>T p.D76= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as rs761293721, COSV57356774, COSV57357254; called by muse, mutect2, varscan2
- KALRN | c.684C>T p.D228= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs200074249, COSV53758220; called by mutect2, varscan2
- MCF2 | c.1452C>A p.S484= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100644800, COSV100645229; called by muse, mutect2, varscan2
- MRPL36 | c.90A>G p.L30= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs749561344, COSV56876308; called by muse, mutect2, varscan2
- NEB | c.16611C>T p.D5537= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs756345641, COSV50891796; called by muse, mutect2, varscan2
- NPHS1 | c.3426G>A p.L1142= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as COSV62286296; called by muse, mutect2
- OR5R1 | c.900C>G p.A300= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV56571822; called by muse, mutect2, varscan2
- PLCL1 | c.1338A>C p.V446= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV70823828; called by muse, mutect2, varscan2
- PNMA1 | c.363T>C p.R121= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV54093622; called by muse, mutect2
- PRDM2 | c.5055G>A p.A1685= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs777213855, COSV52444477; called by muse, mutect2
- PRPSAP1 | c.894G>A p.A298= | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as rs749789101, COSV61210564; called by muse, mutect2
- ST8SIA5 | c.852C>T p.N284= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs770653498, COSV59330321; called by muse, mutect2
- ZNF470 | c.534G>T p.G178= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100401315, COSV57968184; called by muse, mutect2, varscan2
- PNCK | c.-2-160G>T | Intron (SNP) | VAF 3/41 reads (7%) | catalogued as COSV61744934; called by muse, mutect2
- UVSSA | c.*9133G>A | 3'UTR (SNP) | VAF 15/23 reads (65%) | catalogued as rs201883654; called by muse, mutect2, varscan2
